Somatic mutation profile of tumor specimen MBCProject_0346_T1_WES (aliquot MBCProject_0346_T1_WES_1) from CMI case MBCProject_0346, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0346_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f955b942-d193-4f83-9566-015f931b618a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0346_SALIVA (Saliva), aliquot MBCProject_0346_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17edb9ca-b5d6-4309-b8ba-d3823a6034b8

The open-access MAF lists 69 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Intron 5, RNA 2, Nonsense Mutation 1, 5'UTR 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 68/326 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADH1C | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.127); catalogued as rs748191499; called by muse, mutect2
- CCDC88C | c.6001C>T p.R2001* | Nonsense Mutation (SNP) | VAF 23/258 reads (9%) | catalogued as COSV57797524; called by muse, mutect2
- CTCF | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV50486390; called by muse, mutect2
- DMAC2L | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1290309838; called by muse, mutect2, varscan2
- DYNC1H1 | c.11515G>A p.V3839I | Missense Mutation (SNP) | VAF 28/509 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs1216705331; called by muse, mutect2
- FBXO33 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs904377528, COSV53235611; called by muse, mutect2
- GRHPR | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1357326535; called by muse, mutect2
- HTRA3 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56471042; called by muse, mutect2, varscan2
- MYO3B | c.3469A>G p.K1157E | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV58712312; called by muse, mutect2
- PCDHA4 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 90/339 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1379248044, COSV63539339; called by muse, mutect2, varscan2
- SALL1 | c.2582C>T p.S861L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs749947651, CM145985, COSV51752655; called by mutect2, varscan2
- SHROOM4 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 45/342 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1064796301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAF3IP3 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV50557891; called by muse, mutect2
- XPO1 | c.1844T>C p.L615S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68945823; called by muse, varscan2
- ZNF564 | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV100213149; called by muse, mutect2, varscan2
- ADAMTSL4 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 96/471 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CAMSAP2 | c.949T>G p.S317A (on ENST00000236925 / NM_001297707.2; = p.S306A on NM_203459.3) | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CDC45 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CEP126 | c.998A>C p.K333T | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.331); called by muse, mutect2
- DNAH7 | c.2421A>T p.L807F | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DNHD1 | c.5065A>C p.N1689H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFR3A | c.2080T>A p.S694T | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.139); called by muse, mutect2
- HERC1 | c.9714C>G p.S3238R | Missense Mutation (SNP) | VAF 51/489 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- MCM3AP | c.4114C>A p.Q1372K | Missense Mutation (SNP) | VAF 28/738 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.104); called by muse, mutect2
- MYO5A | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NPHS1 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4N5 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR4N5 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- PIP5K1B | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ROS1 | c.4817C>T p.T1606I | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPL10 | c.493-6C>A | Splice Region (SNP) | VAF 46/757 reads (6%) | called by muse, mutect2
- SARM1 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 42/984 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC10A4 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 95/504 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPEN | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STRN4 | c.1716C>A p.D572E | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- STYXL2 | c.2774G>T p.S925I | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2
- TASP1 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 31/401 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM132C | c.591G>C p.E197D | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TOX | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); called by muse, mutect2
- TTC21B | c.2405T>C p.L802S | Missense Mutation (SNP) | VAF 43/507 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- UNC5D | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- UQCRHL | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- WNK3 | c.5204G>C p.G1735A | Missense Mutation (SNP) | VAF 135/300 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ZFPM2 | c.2608C>A p.L870M | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF420 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.412); called by muse, mutect2
- CACNB1 | c.978C>T p.I326= | Silent (SNP) | VAF 28/749 reads (4%) | called by muse, mutect2
- CRIP1 | c.24C>T p.N8= | Silent (SNP) | VAF 47/610 reads (8%) | called by muse, mutect2
- FCGBP | c.9237C>T p.C3079= | Silent (SNP) | VAF 33/267 reads (12%) | catalogued as rs144935006; called by muse, mutect2, varscan2
- H2AC8 | c.234C>G p.R78= | Silent (SNP) | VAF 18/508 reads (4%) | called by muse, mutect2
- HAO2 | c.174G>C p.V58= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV58040789; called by muse, mutect2, varscan2
- NRK | c.1047A>G p.E349= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- OR4N5 | c.249G>T p.V83= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- PHF21B | c.1080A>C p.R360= | Silent (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2, varscan2
- RIPK4 | c.102G>T p.G34= | Silent (SNP) | VAF 72/948 reads (8%) | called by muse, mutect2
- RTN4R | c.987G>A p.P329= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as rs569528258; called by muse, mutect2, varscan2
- SLC2A3 | c.444T>A p.T148= | Silent (SNP) | VAF 54/395 reads (14%) | catalogued as COSV50000962; called by muse, mutect2, varscan2
- SLC34A2 | c.1833C>T p.T611= | Silent (SNP) | VAF 40/740 reads (5%) | called by muse, mutect2
- TUT1 | c.1092C>G p.A364= | Silent (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- USP2 | c.588C>T p.V196= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs35832174, COSV52727087; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827715 A>G | 3'Flank (SNP) | VAF 128/612 reads (21%) | called by muse, mutect2, varscan2
- B3GALT5 | c.-523-7264G>T | Intron (SNP) | VAF 52/652 reads (8%) | called by muse, mutect2
- GVINP1 | n.3237C>G | RNA (SNP) | VAF 18/105 reads (17%) | catalogued as rs1388168336; called by muse, mutect2, varscan2
- KLK3 | c.631-405T>C | Intron (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2, varscan2
- MFSD1 | c.163+219C>G | Intron (SNP) | VAF 100/339 reads (29%) | catalogued as rs1432676241; called by muse, mutect2, varscan2
- PRELID3A | c.-34C>G | 5'UTR (SNP) | VAF 11/142 reads (8%) | catalogued as rs892699932; called by muse, mutect2
- UMODL1 | c.1899+77G>T | Intron (SNP) | VAF 47/424 reads (11%) | called by muse, mutect2, varscan2
- USP3 | c.92-3532C>T | Intron (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- ZNF658B | n.1979C>T | RNA (SNP) | VAF 27/412 reads (7%) | called by muse, mutect2
